Somatic mutation profile of tumor specimen TCGA-V1-A9OQ-01A (aliquot TCGA-V1-A9OQ-01A-11D-A41K-08) from TCGA case TCGA-V1-A9OQ, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A9OQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39356748-e133-4511-86a8-9ab591e81691.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A9OQ-10A (Blood Derived Normal), aliquot TCGA-V1-A9OQ-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/187ef79e-1468-4575-b406-1a9c9949416c

The open-access MAF lists 44 somatic variants for this specimen: 35 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 26, Silent 9, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 2, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANOS1 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 12/17 reads (71%) | catalogued as COSV99391485; called by muse, mutect2, varscan2
- CDKN1B | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 6/81 reads (7%) | catalogued as COSV57431620, COSV99963911; called by muse, mutect2
- CSMD2 | c.7744C>T p.R2582C | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.505); catalogued as rs778412668, COSV53964017; called by muse, mutect2, varscan2
- DDX60 | c.1657A>G p.I553V | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101190702; called by muse, mutect2, varscan2
- DNM1L | c.1458A>T p.L486F | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV99846483; called by muse, mutect2
- GALNT3 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs200762567; called by muse, mutect2
- GPANK1 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.397); catalogued as rs1248835838, COSV63263903; called by muse, mutect2, varscan2
- GRM3 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV64466957; called by muse, mutect2, varscan2
- GUCY1A2 | c.651G>C p.Q217H | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV99977147; called by muse, mutect2, varscan2
- HACD4 | c.212A>G p.E71G | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101529967; called by muse, mutect2
- IGSF10 | c.2725A>G p.M909V | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99196350; called by muse, mutect2
- IL22RA2 | c.340C>A p.Q114K | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.193); catalogued as COSV99760847; called by muse, mutect2, varscan2
- LCOR | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100603862; called by muse, mutect2, varscan2
- MIOS | c.2296T>A p.S766T | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.76); PolyPhen benign (0.039); catalogued as COSV100402970; called by muse, mutect2, varscan2
- NAPSA | c.1027G>A p.V343I | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.995); catalogued as rs958024903, COSV53797179; called by muse, mutect2
- NECTIN3 | c.918-2A>G p.X306_splice | Splice Site (SNP) | VAF 4/47 reads (9%) | catalogued as COSV100162772; called by muse, mutect2
- NPR2 | c.1234T>G p.S412A | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.03); catalogued as COSV100709759; called by muse, mutect2, varscan2
- NT5DC3 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 65/200 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101231050; called by muse, mutect2, varscan2
- OR10AG1 | c.156T>G p.F52L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100400221; called by muse, mutect2, varscan2
- OR7D2 | c.178T>A p.Y60N | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100713091; called by muse, mutect2, varscan2
- PCDH11X | c.2693G>A p.S898N | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100015571, COSV53457731; called by muse, mutect2, varscan2
- PELI1 | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100735196; called by muse, mutect2, varscan2
- PTPRK | c.3241C>G p.H1081D (on ENST00000368215 / NM_001291984.2; = p.H1082D on NM_002844.4) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100951630; called by muse, mutect2, varscan2
- RPN2 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV99412115; called by muse, mutect2
- SETD2 | c.4246G>T p.E1416* | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as COSV100340116; called by muse, mutect2, varscan2
- SHQ1 | c.694A>G p.K232E | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0.01); catalogued as rs1285556409, COSV100345407; called by muse, mutect2, varscan2
- TET3 | c.1741A>C p.K581Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.301); catalogued as rs372872964; called by muse, varscan2
- TLR4 | c.472G>T p.A158S (on ENST00000355622 / NM_138554.5; = p.A118S on NM_003266.4) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.56); catalogued as rs1286055523, COSV100790698; called by muse, mutect2, varscan2
- TMCC2 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.012); catalogued as COSV100788370; called by muse, mutect2
- WBP4 | c.811del p.S271Vfs*8 | Frame Shift Del (DEL) | VAF 18/45 reads (40%) | catalogued as rs1354613512; called by mutect2, pindel, varscan2
- ZNF48 | c.1856G>T p.*619Lext*19 | Nonstop Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100198238; called by muse, mutect2, varscan2
- ZNF653 | c.1547G>A p.R516Q | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs1187479562, COSV99542202; called by muse, mutect2
- ATP5PB | c.202del p.Y68Ifs*6 | Frame Shift Del (DEL) | VAF 33/123 reads (27%) | called by mutect2, pindel, varscan2
- CD274 | c.394+4_394+10del p.X132_splice | Splice Site (DEL) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- GON4L | c.3647dup p.I1217Yfs*6 | Frame Shift Ins (INS) | VAF 15/51 reads (29%) | called by mutect2, varscan2
- DBF4B | c.1821C>T p.C607= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as rs368247640; called by mutect2, varscan2
- LY6K | c.54C>T p.D18= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs375943074; called by muse, mutect2, varscan2
- PPP1R16A | c.1185C>T p.L395= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV99477871; called by muse, mutect2
- PRAMEF4 | c.21T>C p.T7= | Silent (SNP) | VAF 22/206 reads (11%) | catalogued as COSV99340272; called by muse, mutect2
- RPL10A | c.192T>A p.S64= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100003612; called by muse, mutect2, varscan2
- RPP30 | c.705A>G p.R235= | Silent (SNP) | VAF 46/148 reads (31%) | catalogued as COSV99521051; called by muse, mutect2, varscan2
- SHC3 | c.1224G>A p.T408= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as rs369413725; called by muse, mutect2, varscan2
- TPD52L1 | c.555C>G p.A185= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV100509507; called by muse, mutect2, varscan2
- VANGL2 | c.1440A>G p.L480= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV100925620, COSV63605598; called by muse, mutect2, varscan2
